CCDI case PBCJJF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/fec8996f-f1bf-4d73-bbd0-d845dc04f82c

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 12.5 years (4,563 days).

Biospecimens (2 samples)
- Sample 0DTGDB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DTGDG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
